Somatic mutation profile of tumor specimen BA2594D (aliquot aq-BA2594D) from BEATAML1.0 case 2554, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.5 years (26,494 days).
Specimen BA2594D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f00d2072-e606-42b5-96eb-af2e636b45a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2187D (Solid Tissue Normal), aliquot aq-BA2187D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccd3ac07-fd4b-404d-b1d9-788663f8b3a2

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- LETMD1 | c.368G>C p.R123P | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100016534, COSV50397728; called by muse, mutect2, varscan2
- MYOM1 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99867454; called by muse, mutect2
- XKR6 | c.1545G>T p.E515D | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.675); called by muse, mutect2
- CCER1 | chr12:90947984 C>A | 3'Flank (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- KLF6 | c.*258G>T | 3'UTR (SNP) | VAF 6/93 reads (6%) | catalogued as rs1016927624; called by muse, mutect2
